Somatic mutation profile of tumor specimen TCGA-ET-A2N5-01A (aliquot TCGA-ET-A2N5-01A-11D-A18F-08) from TCGA case TCGA-ET-A2N5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.9 years (17,137 days).
Specimen TCGA-ET-A2N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dc7529f-24a4-4914-a767-1b83e1e06bd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2N5-11B (Solid Tissue Normal), aliquot TCGA-ET-A2N5-11B-11D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccae47cf-be73-48bc-bf79-6694d8e1f771

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 40/102 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.3896G>A p.G1299D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as rs1416591993, COSV60115642; called by muse, mutect2, varscan2
- BCAP31 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54386860; called by muse, mutect2
- CEP250 | c.3827C>T p.T1276I | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs773870781, COSV61172398; called by muse, mutect2, varscan2
- CLCN2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs201130753; called by muse, mutect2, varscan2
- EPHA6 | c.3325A>G p.I1109V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV67585638; called by muse, mutect2
- PTPRB | c.4461C>A p.Y1487* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV54248503; called by muse, mutect2, varscan2
- ZFP90 | c.1839A>T p.E613D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.495); catalogued as COSV68051200; called by muse, mutect2, varscan2
- ZNF491 | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV60058363; called by muse, mutect2, varscan2
- SOX2 | c.118del p.R40Afs*6 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | called by mutect2, pindel, varscan2
